Somatic mutation profile of tumor specimen BA2211D (aliquot aq-BA2211D) from BEATAML1.0 case 2471, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.0 years (24,090 days).
Specimen BA2211D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2e541be-0738-4183-8e56-4cc9e070d324.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2389D (Solid Tissue Normal), aliquot aq-BA2389D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54bcf717-8405-4cfc-ac25-f7231e3be56f

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/41 reads (32%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PANK3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 14/158 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs77612793; called by mutect2, varscan2
- CHST8 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs777164663, COSV52858558; called by muse, mutect2, varscan2
- FADS2 | c.206C>A p.T69K | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- KLHL10 | c.1775C>A p.A592E | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.283); called by muse, mutect2
- SLC1A5 | c.1278G>T p.V426= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as rs1159142635; called by muse, mutect2
- PLEKHF1 | c.-17+137C>A | Intron (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- WDR73 | c.517+80G>T | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
